Somatic mutation profile of tumor specimen TCGA-2G-AAH2-01A (aliquot TCGA-2G-AAH2-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAH2, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 20.9 years (7,635 days).
Specimen TCGA-2G-AAH2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e058c2c-0ef5-4af1-a21e-82399a98bf3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAH2-10A (Blood Derived Normal), aliquot TCGA-2G-AAH2-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/755b1ab7-7817-4323-b2eb-3aa675a2aa2d

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KNL1 | c.6659A>T p.H2220L (on ENST00000346991 / NM_170589.5; = p.H2194L on NM_144508.5) | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV61156593; called by muse, mutect2, varscan2
- NCOR1 | c.4337C>T p.S1446F | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs1469460933; called by muse, mutect2, varscan2
- ATP8B2 | c.3482G>T p.G1161V (on ENST00000672630; = p.G1128V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- COL3A1 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAAR2 | c.59del p.K20Rfs*45 | Frame Shift Del (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- TRMU | c.773-1G>C p.X258_splice | Splice Site (SNP) | VAF 85/299 reads (28%) | called by muse, mutect2, varscan2
- MED1 | c.1440C>T p.Y480= | Silent (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- PAXIP1 | c.3012C>T p.S1004= | Silent (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- APEX1 | c.58+11G>C | Intron (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- MOCS2 | c.377+44T>C | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
